Somatic mutation profile of tumor specimen C3N-02253-74 (aliquot CPT0128770006) from CPTAC case C3N-02253, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; Tumor grade: G2.
Specimen C3N-02253-74: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79fd9d61-1dd0-4f3a-834d-cb8922068b7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02253-32 (Blood Derived Normal), aliquot CPT0130760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6099dad6-5a16-4624-b85f-a208d29b46fd

The open-access MAF lists 5,378 somatic variants for this specimen: 3,847 protein-altering or splice-affecting, 873 silent, 658 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,195, Silent 873, Nonsense Mutation 507, Intron 322, RNA 120, 3'UTR 113, Splice Site 82, 5'UTR 49, Splice Region 44, 5'Flank 32, 3'Flank 21, Frame Shift Ins 8.

Variants (750 of 5,378; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANOS1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 101/314 reads (32%) | catalogued as rs137852516, CM021282, COSV52920162; ClinVar: pathogenic; called by muse, varscan2
- APC | c.1433T>G p.L478* | Nonsense Mutation (SNP) | VAF 88/227 reads (39%) | catalogued as rs863225314, CM130054, COSV104379113, COSV57323854; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 145/363 reads (40%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.4966G>T p.E1656* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as rs62638179, CM063894, COSV58350032; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFTR | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs397508342, CM024683, COSV50043054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL17A1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 131/404 reads (32%) | catalogued as rs121912774, CM001969, COSV62225489; ClinVar: pathogenic; called by muse, varscan2
- COL4A5 | c.5030G>A p.R1677Q | Missense Mutation (SNP) | VAF 103/292 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886308, CM010201, CM113173, CM970369, COSV60366574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304504006, CM091938, COSV54205813; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs797045041, COSV58292419; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- F13A1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913072, CM960521, COSV53561772; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FAM161A | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 89/203 reads (44%) | catalogued as rs267606794, CM105647, COSV56765545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 121/350 reads (35%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- GRIA3 | c.2497G>A p.G833R | Missense Mutation (SNP) | VAF 129/335 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852350, CM074896; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRP5 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 33/411 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs376152274, CM103443; ClinVar: likely pathogenic; called by muse, mutect2
- MCPH1 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906961, CM107962, COSV100766054; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 120/279 reads (43%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 42/111 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CB | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs1451809865, COSV56683754; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 81/109 reads (74%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 122/328 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PRDM6 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs879255278, CM166493, COSV68337766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRKCI | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs1388201066, COSV55517137, COSV55517929; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 138/392 reads (35%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPS6KA3 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs122454127, CM992428, COSV65387529; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPAST | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1553317025, CM022250; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SRPX2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 186/505 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1556013503, COSV100883977, COSV65933194; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TNNT3 | c.220C>T p.R74C (on ENST00000397301 / NM_001367846.1; = p.R63C on NM_006757.4) | Missense Mutation (SNP) | VAF 162/421 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs199474721, CM112791, CM131700, COSV53486520; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 157/396 reads (40%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.56572C>T p.R18858* (on ENST00000591111; = p.R11434* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs869312112, CM121824, COSV59933111; ClinVar: likely pathogenic; called by mutect2, varscan2
- TWNK | c.1106C>A p.S369Y | Missense Mutation (SNP) | VAF 213/571 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs111033579, CM023775; ClinVar: pathogenic; called by muse, mutect2, varscan2
- UQCRFS1 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 67/216 reads (31%) | catalogued as rs1242465339; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs761651104; called by muse, mutect2, varscan2
- AARS1 | c.395G>T p.R132I | Missense Mutation (SNP) | VAF 68/520 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs78325403; called by muse, mutect2, varscan2
- ABCA10 | c.2664G>T p.K888N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52218066; called by muse, mutect2, varscan2
- ABCA12 | c.1301G>A p.R434Q (on ENST00000272895 / NM_173076.3; = p.R116Q on NM_015657.3) | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs745415552, COSV55947973; called by muse, mutect2, varscan2
- ABCA12 | c.1231C>T p.R411C (on ENST00000272895 / NM_173076.3; = p.R93C on NM_015657.3) | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs774434795, COSV55950674; called by muse, mutect2, varscan2
- ABCA13 | c.7048G>T p.E2350* | Nonsense Mutation (SNP) | VAF 34/69 reads (49%) | catalogued as COSV71284578, COSV71286769; called by muse, mutect2, varscan2
- ABCA6 | c.2907G>T p.K969N | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99447624; called by muse, mutect2, varscan2
- ABCA7 | c.2555C>T p.S852F | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755744816; called by muse, mutect2, varscan2
- ABCA7 | c.4598C>T p.S1533L | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs776920026, COSV54026755; called by muse, mutect2, varscan2
- ABCA8 | c.4147A>C p.K1383Q | Missense Mutation (SNP) | VAF 105/252 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1333489267; called by muse, mutect2, varscan2
- ABCB1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 16/186 reads (9%) | catalogued as rs1222604496, COSV55945529; called by muse, mutect2
- ABCB5 | c.2948C>T p.S983L (on ENST00000404938 / NM_001163941.2; = p.S538L on NM_178559.6) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.613); catalogued as COSV51706637; called by muse, varscan2
- ABCC4 | c.1810C>A p.L604M | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); catalogued as COSV99061142; called by muse, mutect2, varscan2
- ABCC8 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 163/422 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs765028814; called by muse, mutect2, varscan2
- ABCC9 | c.4039C>T p.R1347C | Missense Mutation (SNP) | VAF 136/382 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53980840; called by muse, mutect2, varscan2
- ABHD8 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV53113045; called by muse, mutect2, varscan2
- ABL1 | c.3359C>T p.S1120L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs1456042173, COSV59334185; called by muse, mutect2, varscan2
- ABRA | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.78); catalogued as COSV61732358, COSV61732643; called by muse, mutect2, varscan2
- AC008397.2 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs763707510, COSV53206848; called by muse, mutect2, varscan2
- ACADM | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1160997519; called by muse, mutect2, varscan2
- ACE2 | c.1990C>A p.L664I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.06); catalogued as COSV53023908; called by muse, mutect2, varscan2
- ACIN1 | c.1802C>A p.S601Y | Missense Mutation (SNP) | VAF 103/293 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV104392097; called by muse, mutect2, varscan2
- ACKR1 | c.78G>A p.W26* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | catalogued as COSV63674583; called by muse, mutect2, varscan2
- ACOD1 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.158); catalogued as rs757432360; called by muse, mutect2, varscan2
- ACSF3 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 105/305 reads (34%) | catalogued as COSV58077304; called by muse, mutect2, varscan2
- ACSM3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 108/265 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1267372126, COSV55500169, COSV55502645; called by muse, mutect2, varscan2
- ACTL8 | c.998G>T p.R333I | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV64860966; called by muse, mutect2, varscan2
- ADAM29 | c.1488G>T p.K496N | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV63666888, COSV63667955; called by muse, mutect2, varscan2
- ADAMTS2 | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 119/334 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs979855168, COSV52365317; called by muse, mutect2, varscan2
- ADAMTS20 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV67134539; called by muse, mutect2, varscan2
- ADAMTS5 | c.2281C>T p.R761* | Nonsense Mutation (SNP) | VAF 34/75 reads (45%) | catalogued as rs777065435, COSV53177958; called by muse, mutect2, varscan2
- ADAMTS7 | c.3196G>A p.D1066N | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs769609028; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4039C>T p.L1347F | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs768511056; called by muse, mutect2, varscan2
- ADCY9 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.678); catalogued as rs779440212, COSV53575360; called by muse, mutect2, varscan2
- ADGRF5 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 55/111 reads (50%) | catalogued as COSV51937265; called by muse, mutect2, varscan2
- ADGRG4 | c.5098C>A p.L1700I | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV99795772; called by muse, mutect2, varscan2
- ADGRG4 | c.7777-1G>T p.X2593_splice | Splice Site (SNP) | VAF 44/87 reads (51%) | catalogued as COSV54959562, COSV54961749; called by muse, mutect2, varscan2
- ADGRG5 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs767544968; called by muse, mutect2, varscan2
- ADGRV1 | c.9989G>T p.R3330I | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV67984740, COSV67989632; called by muse, mutect2, varscan2
- ADH7 | c.1082T>C p.V361A | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV104392995; called by muse, mutect2, varscan2
- ADORA3 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 147/343 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs776955833; called by muse, mutect2, varscan2
- ADRA1A | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as rs1354852913; called by muse, mutect2, varscan2
- ADRA2B | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 194/507 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs1278462619, COSV69787669; called by muse, mutect2, varscan2
- AEBP1 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs779044302, COSV99788780; called by muse, mutect2, varscan2
- AEBP2 | c.1313G>T p.R438I | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56861458; called by muse, mutect2, varscan2
- AGK | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780744663, COSV62594437; called by muse, mutect2, varscan2
- AGXT2 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 201/564 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51483920; called by muse, mutect2, varscan2
- AHNAK2 | c.17093G>A p.R5698Q | Missense Mutation (SNP) | VAF 116/315 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767692317, COSV60911646; called by muse, mutect2, varscan2
- AHNAK2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1311575783, COSV60908486; called by muse, mutect2
- AK5 | c.700-1G>T p.X234_splice (on ENST00000354567 / NM_174858.3; = p.X208_splice on NM_012093.4) | Splice Site (SNP) | VAF 46/98 reads (47%) | catalogued as COSV60968620; called by muse, mutect2, varscan2
- AKAP4 | c.2247G>T p.Q749H | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV62073548; called by muse, mutect2, varscan2
- AKAP6 | c.3688A>T p.S1230C | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs753879624; called by muse, mutect2, varscan2
- AKAP9 | c.2962G>T p.E988* | Nonsense Mutation (SNP) | VAF 47/117 reads (40%) | catalogued as rs754493921; called by muse, mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 136/339 reads (40%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2, varscan2
- AKR1C2 | c.632T>G p.I211S | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66333211; called by muse, mutect2, varscan2
- AKR1C3 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs782758217, COSV101003092; called by muse, mutect2, varscan2
- AKR1D1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 117/327 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs779758762, COSV54339065; called by muse, mutect2, varscan2
- ALG10 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 191/476 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283038610; called by muse, mutect2, varscan2
- ALG10B | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 125/366 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756608323; called by muse, mutect2, varscan2
- ALG11 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201526759, COSV73000831; called by muse, varscan2
- ALG13 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs1455053208; called by muse, mutect2, varscan2
- ALG5 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs908081645; called by muse, mutect2, varscan2
- ALLC | c.34-1G>T p.X12_splice | Splice Site (SNP) | VAF 56/163 reads (34%) | catalogued as COSV52994480, COSV99377368; called by muse, mutect2, varscan2
- ALMS1 | c.5991G>T p.K1997N | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV100043203; called by muse, mutect2, varscan2
- ALOX12 | c.1845C>A p.F615L | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52349344; called by muse, mutect2, varscan2
- ALOX5 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV65552322; called by muse, mutect2, varscan2
- ALOXE3 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 69/466 reads (15%) | catalogued as COSV59073935; called by muse, varscan2
- AMER3 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 35/85 reads (41%) | catalogued as COSV58466116, COSV58466188; called by muse, mutect2, varscan2
- AMMECR1L | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 117/343 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55761756; called by muse, mutect2, varscan2
- AMPD1 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 141/393 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815206, COSV62417288; called by muse, mutect2, varscan2
- AMPD1 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 165/371 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV62420055; called by muse, mutect2, varscan2
- AMPD3 | c.2135A>C p.Q712P (on ENST00000396553 / NM_001025389.2; = p.Q721P on NM_000480.3) | Missense Mutation (SNP) | VAF 96/208 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as CM003129; called by muse, varscan2
- AMY2A | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 140/456 reads (31%) | catalogued as rs566657194; called by muse, mutect2, varscan2
- ANHX | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 100/315 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs745541726; called by muse, mutect2, varscan2
- ANK2 | c.6082C>T p.R2028W | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1411026310, COSV52150851; called by muse, mutect2, varscan2
- ANK2 | c.10804C>T p.R3602* | Nonsense Mutation (SNP) | VAF 127/279 reads (46%) | catalogued as COSV52152721; called by muse, mutect2, varscan2
- ANKRD20A4P | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs763901241; called by mutect2, varscan2
- ANKRD26 | c.4744G>A p.E1582K | Missense Mutation (SNP) | VAF 113/380 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV65776569; called by muse, mutect2, varscan2
- ANKRD30A | c.1663G>T p.E555* (on ENST00000611781; = p.E499* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 49/149 reads (33%) | catalogued as COSV64610041; called by muse, mutect2, varscan2
- ANKRD30A | c.2564C>A p.S855Y (on ENST00000611781; = p.S799Y on NM_052997.2) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as COSV64609645; called by muse, mutect2, varscan2
- ANKRD30B | c.2254G>T p.E752* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as rs1370237272, COSV62819000; called by muse, mutect2, varscan2
- ANKRD30B | c.3366G>T p.K1122N | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs770804485, COSV57701874; called by muse, mutect2, varscan2
- ANKRD36C | c.2609C>T p.S870L | Missense Mutation (SNP) | VAF 129/345 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.887); catalogued as rs767323942; called by muse, mutect2, varscan2
- ANKRD45 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100322411; called by muse, mutect2, varscan2
- ANKRD55 | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61950126; called by muse, mutect2, varscan2
- ANKRD62 | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | catalogued as COSV58411014; called by muse, mutect2, varscan2
- ANKS1B | c.2594G>T p.R865I (on ENST00000547776 / NM_152788.4; = p.R91I on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV60362771; called by muse, mutect2, varscan2
- ANO4 | c.629G>A p.R210Q (on ENST00000392977 / NM_001286615.2; = p.R175Q on NM_178826.4) | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs199651099; called by muse, mutect2, varscan2
- ANO4 | c.2650C>T p.R884* (on ENST00000392977 / NM_001286615.2; = p.R849* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 90/279 reads (32%) | catalogued as rs1195067838, COSV54604774; called by muse, mutect2, varscan2
- ANO5 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 122/345 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs199532484, CM137911, COSV61084245; called by muse, mutect2, varscan2
- AP3D1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61430826; called by muse, mutect2, varscan2
- APC | c.4565T>G p.L1522* | Nonsense Mutation (SNP) | VAF 69/215 reads (32%) | catalogued as COSV57357937; called by muse, mutect2, varscan2
- APOB | c.11607C>A p.F3869L | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.065); catalogued as COSV51942607, COSV51954942; called by muse, mutect2, varscan2
- APOL6 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs780403475, COSV68749391; called by muse, mutect2, varscan2
- APPL2 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 42/134 reads (31%) | catalogued as COSV51593514; called by muse, mutect2, varscan2
- AQP12B | c.173A>C p.D58A (on ENST00000621682; = p.D70A on NM_001102467.2) | Missense Mutation (SNP) | VAF 185/594 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381201545; called by muse, mutect2, varscan2
- ARAP3 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as rs575984491; called by muse, mutect2, varscan2
- ARHGAP10 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 151/400 reads (38%) | catalogued as COSV60595214; called by muse, mutect2, varscan2
- ARHGAP15 | c.1113C>A p.F371L | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1421502107, COSV99710671; called by muse, mutect2, varscan2
- ARHGAP18 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 49/116 reads (42%) | catalogued as rs969461309, COSV63764944; called by muse, mutect2, varscan2
- ARHGAP18 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as COSV63766017; called by muse, mutect2, varscan2
- ARHGAP21 | c.4772C>T p.S1591L | Missense Mutation (SNP) | VAF 123/315 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs767734882, COSV57602396; called by muse, mutect2, varscan2
- ARHGAP21 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770619381; called by muse, mutect2, varscan2
- ARHGAP24 | c.2155C>T p.Q719* (on ENST00000395184 / NM_001025616.3; = p.Q626* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 46/447 reads (10%) | catalogued as rs1358236786; called by muse, mutect2, varscan2
- ARHGAP26 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1191015382, COSV50835979; called by muse, mutect2, varscan2
- ARHGAP30 | c.2929G>T p.E977* (on ENST00000368013 / NM_001025598.2; = p.E766* on NM_181720.3) | Nonsense Mutation (SNP) | VAF 68/171 reads (40%) | catalogued as COSV63515376; called by muse, mutect2, varscan2
- ARHGEF26 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 114/339 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.416); catalogued as rs1236611691; called by muse, mutect2, varscan2
- ARHGEF6 | c.18A>C p.Q6H | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV51695689; called by muse, varscan2
- ARHGEF6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 124/290 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV51696679; called by muse, varscan2
- ARMCX1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.816); catalogued as rs1453790724, COSV65705450; called by muse, mutect2
- ARMCX3 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57869954; called by muse, mutect2, varscan2
- ARMCX3 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as COSV57869828; called by muse, mutect2, varscan2
- ARMT1 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.648); catalogued as COSV66179107; called by muse, mutect2, varscan2
- ARNTL2 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757395444, COSV53825158, COSV53828394; called by muse, mutect2, varscan2
- ARRB1 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs960206608; called by muse, mutect2
- ARSJ | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 37/180 reads (21%) | catalogued as rs768960135, COSV59538126, COSV59538717, COSV59540375; called by muse, mutect2, varscan2
- ASB2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 195/499 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs866197152; called by muse, mutect2, varscan2
- ASB7 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 52/138 reads (38%) | catalogued as COSV60417431; called by muse, mutect2, varscan2
- ASCC3 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.219); catalogued as rs199548862; called by muse, mutect2, varscan2
- ASH1L | c.8227C>T p.R2743W (on ENST00000368346 / NM_001366177.2; = p.R2738W on NM_018489.3) | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64213590; called by muse, mutect2, varscan2
- ASH2L | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99166983; called by muse, mutect2, varscan2
- ASPM | c.10274C>A p.S3425Y | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV54127420, COSV54137455, COSV99659149; called by muse, mutect2, varscan2
- ASXL3 | c.2420C>T p.T807I | Missense Mutation (SNP) | VAF 99/254 reads (39%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV52464713; called by muse, mutect2, varscan2
- ASXL3 | c.3827C>T p.A1276V | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.193); catalogued as rs780579011; called by muse, mutect2, varscan2
- ATAD5 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV58971869; called by muse, mutect2, varscan2
- ATG7 | c.928G>T p.G310* | Nonsense Mutation (SNP) | VAF 65/175 reads (37%) | catalogued as rs1174451964; called by muse, mutect2, varscan2
- ATIC | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs199518893, COSV52692257; called by muse, mutect2, varscan2
- ATP10B | c.3408C>A p.F1136L | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59150509, COSV59156779; called by muse, mutect2, varscan2
- ATP10D | c.820T>G p.L274V | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV56713526; called by muse, mutect2, varscan2
- ATP11B | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 81/192 reads (42%) | catalogued as rs1295948091, COSV60026923; called by muse, mutect2, varscan2
- ATP11C | c.3299G>T p.R1100I | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1350755139, COSV100558364; called by muse, mutect2, varscan2
- ATP12A | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 22/526 reads (4%) | catalogued as COSV104374365, COSV54522715; called by muse, mutect2
- ATP13A3 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs375152534, COSV99756488; called by muse, mutect2, varscan2
- ATP13A5 | c.1717T>C p.S573P | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs747985085; called by muse, mutect2, varscan2
- ATP1B1 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 22/128 reads (17%) | catalogued as COSV100891630; called by muse, mutect2
- ATP1B3 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 97/233 reads (42%) | catalogued as COSV53950226; called by muse, mutect2, varscan2
- ATP1B4 | c.772C>T p.R258C (on ENST00000218008 / NM_001142447.3; = p.R254C on NM_012069.5) | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as rs149447498, COSV54312900; called by muse, mutect2, varscan2
- ATP6AP2 | c.1039C>T p.R347* (on ENST00000378438; = p.R348* on NM_005765.3) | Nonsense Mutation (SNP) | VAF 53/138 reads (38%) | catalogued as COSV65797151; called by muse, varscan2
- ATP6V0D2 | c.262C>A p.H88N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1372328131; called by muse, mutect2, varscan2
- ATP6V1B1 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 278/771 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV52270399; called by muse, mutect2, varscan2
- ATP7A | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 116/323 reads (36%) | catalogued as COSV58450678; called by muse, mutect2, varscan2
- ATP8A1 | c.2441T>C p.V814A | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs1044887319; called by muse, mutect2
- ATP8A1 | c.722+2T>C p.X241_splice | Splice Site (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100046371; called by muse, varscan2
- ATP8A2 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs535509828, COSV54936164, COSV99680731; called by muse, mutect2, varscan2
- ATP8B3 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 132/392 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs368521166; called by muse, mutect2, varscan2
- ATP8B4 | c.1393C>A p.H465N | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV52725458; called by muse, mutect2, varscan2
- ATRX | c.3512G>T p.R1171I | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV64874523; called by muse, mutect2, varscan2
- ATXN2 | c.1538C>A p.S513* (on ENST00000550104; = p.S353* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 63/156 reads (40%) | catalogued as COSV101112892; called by muse, mutect2, varscan2
- ATXN2L | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 106/280 reads (38%) | catalogued as COSV57378398; called by muse, mutect2, varscan2
- AXDND1 | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 85/241 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62645197; called by muse, mutect2, varscan2
- AXL | c.2348C>T p.S783L (on ENST00000301178 / NM_021913.5; = p.S774L on NM_001699.6) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.289); catalogued as rs775504685; called by muse, mutect2, varscan2
- B2M | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 69/422 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62566827; called by muse, mutect2, varscan2
- BAG3 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 122/322 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs140904592, COSV64841916; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAK1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1051911; called by muse, mutect2, varscan2
- BCHE | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100012650; called by muse, mutect2, varscan2
- BCL11B | c.1915G>A p.A639T (on ENST00000357195 / NM_001282237.2; = p.A568T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.365); catalogued as rs757991781; called by muse, mutect2, varscan2
- BCOR | c.3812C>T p.S1271L (on ENST00000378444 / NM_001123385.2; = p.S1237L on NM_017745.6) | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs892857458, COSV60699397, COSV60715837; called by muse, mutect2, varscan2
- BDH1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.753); catalogued as rs1281504554, COSV64019229; called by muse, mutect2, varscan2
- BFAR | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs780598120; called by muse, mutect2, varscan2
- BHMT2 | c.388A>C p.K130Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs960254666; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV57278938; called by muse, mutect2, varscan2
- BMP2 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs765038230; called by muse, mutect2, varscan2
- BMP5 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.895); catalogued as COSV63702143; called by muse, mutect2, varscan2
- BMX | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 127/359 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as COSV100564652, COSV59593880; called by muse, mutect2, varscan2
- BOC | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs1435355183, COSV104383210; called by muse, mutect2, varscan2
- BPIFC | c.1149C>T p.F383= | Splice Region (SNP) | VAF 47/114 reads (41%) | catalogued as rs200868839, COSV55910552; called by muse, mutect2, varscan2
- BRD1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 186/495 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53461826; called by muse, mutect2, varscan2
- BRINP3 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.147); catalogued as rs375567534, COSV66538726; called by muse, mutect2, varscan2
- BRSK1 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV58667719; called by muse, varscan2
- BRWD3 | c.2072C>A p.S691Y | Missense Mutation (SNP) | VAF 92/269 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.163); catalogued as COSV64754475; called by muse, mutect2, varscan2
- BTBD9 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 97/240 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs751618739, COSV58422497; called by muse, mutect2, varscan2
- BTNL3 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1347318248, COSV100732249; called by muse, mutect2
- BZW2 | c.1202T>G p.F401C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51754638; called by muse, mutect2, varscan2
- C12orf40 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV100210416; called by muse, varscan2
- C19orf71 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 227/571 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs557865552; called by muse, mutect2, varscan2
- C1QTNF2 | c.713G>A p.G238E (on ENST00000393975; = p.G193E on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/510 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768806713; called by muse, mutect2, varscan2
- C1QTNF3 | c.441C>A p.F147L | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV51467903; called by muse, mutect2, varscan2
- C1orf105 | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 54/150 reads (36%) | catalogued as COSV100878114; called by muse, mutect2, varscan2
- C1orf35 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184882169; called by muse, mutect2
- C1orf74 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 136/404 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV50551115; called by muse, mutect2, varscan2
- C2orf42 | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs978577289; called by muse, mutect2, varscan2
- C3 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 132/352 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1297252966; called by muse, mutect2, varscan2
- C3orf52 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.428); catalogued as COSV99332608; called by muse, mutect2, varscan2
- C3orf70 | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 127/327 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV58589330; called by muse, mutect2, varscan2
- C4orf51 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 86/254 reads (34%) | catalogued as rs1484682694, COSV71264040; called by muse, varscan2
- C5AR1 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 152/422 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.244); catalogued as rs201964244, COSV61892525; called by muse, mutect2, varscan2
- C6orf118 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs368176728; called by muse, mutect2, varscan2
- C9 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 125/397 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99662360; called by muse, mutect2, varscan2
- CACNA1D | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 108/306 reads (35%) | catalogued as COSV55437189; called by muse, varscan2
- CACNA1E | c.3965C>A p.S1322Y | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV62407041; called by muse, mutect2, varscan2
- CACNA1F | c.3001G>T p.G1001* | Nonsense Mutation (SNP) | VAF 138/390 reads (35%) | catalogued as COSV100544284; called by muse, mutect2, varscan2
- CACNA1H | c.1266C>A p.F422L | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100672910; called by muse, mutect2, varscan2
- CACNA1H | c.3104C>T p.S1035L | Missense Mutation (SNP) | VAF 101/326 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs754242338; called by muse, mutect2, varscan2
- CACNA2D3 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 84/197 reads (43%) | catalogued as rs1553906205, COSV55535714; called by muse, mutect2, varscan2
- CACNA2D4 | c.1161C>A p.F387L | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV54959204; called by muse, mutect2, varscan2
- CAD | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs144305066; called by muse, mutect2, varscan2
- CAD | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs371150372, COSV53027932; called by muse, mutect2, varscan2
- CADM2 | c.641C>T p.P214L (on ENST00000407528 / NM_001167674.2; = p.P216L on NM_153184.4) | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV67388230; called by muse, mutect2
- CADPS2 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 87/211 reads (41%) | catalogued as COSV100460212; called by muse, mutect2, varscan2
- CALCOCO2 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 149/303 reads (49%) | catalogued as COSV51951560; called by muse, mutect2, varscan2
- CALCRL | c.543C>A p.F181L | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1341312655; called by muse, mutect2, varscan2
- CAMK4 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV56662944, COSV56675908; called by muse, mutect2, varscan2
- CAMTA2 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs149046611; called by muse, mutect2, varscan2
- CAND2 | c.2591C>T p.A864V (on ENST00000456430 / NM_001162499.2; = p.A771V on NM_012298.3) | Missense Mutation (SNP) | VAF 103/248 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as rs747207547; called by muse, mutect2, varscan2
- CAPN9 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769257212; called by muse, mutect2, varscan2
- CAPRIN2 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 86/226 reads (38%) | catalogued as COSV51835286; called by muse, mutect2, varscan2
- CARD11 | c.2706C>T p.F902= | Splice Region (SNP) | VAF 68/169 reads (40%) | catalogued as rs372346149; called by muse, mutect2, varscan2
- CARD18 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 116/291 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.105); catalogued as COSV101596041; called by muse, mutect2, varscan2
- CARD6 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs767359554; called by muse, mutect2, varscan2
- CASP1 | c.980T>G p.F327C (on ENST00000436863 / NM_033292.4; = p.F306C on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222240856; called by muse, mutect2, varscan2
- CASP8AP2 | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs779691993; called by muse, mutect2, varscan2
- CASQ2 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54771562; called by muse, mutect2, varscan2
- CATSPER2 | c.1393C>T p.R465C (on ENST00000321596 / NM_001282309.3; = p.R467C on NM_172095.4) | Missense Mutation (SNP) | VAF 117/567 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs542033034, COSV58661105; called by muse, mutect2, varscan2
- CATSPERB | c.1576C>A p.L526I | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99830829; called by muse, mutect2, varscan2
- CATSPERE | c.2329G>T p.D777Y | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100835273; called by muse, varscan2
- CBX3 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 67/222 reads (30%) | catalogued as COSV61761318; called by muse, mutect2, varscan2
- CC2D2B | c.62G>T p.R21I | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV60358602; called by muse, mutect2, varscan2
- CCAR1 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56268629; called by muse, mutect2, varscan2
- CCDC141 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs772733146, COSV55371515; called by muse, mutect2, varscan2
- CCDC141 | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1436512242; called by muse, mutect2, varscan2
- CCDC157 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.386); catalogued as rs746192462; called by muse, mutect2, varscan2
- CCDC160 | c.540dup p.E181Rfs*20 | Frame Shift Ins (INS) | VAF 52/201 reads (26%) | catalogued as rs1436795808; called by mutect2, pindel, varscan2
- CCDC160 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 63/184 reads (34%) | catalogued as COSV66251579; called by muse, mutect2, varscan2
- CCDC168 | c.19746G>T p.K6582N | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV100487806, COSV59423851; called by muse, mutect2, varscan2
- CCDC175 | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.05); catalogued as rs1445399946; called by muse, mutect2, varscan2
- CCDC18 | c.3103C>A p.R1035S (on ENST00000343253 / NM_001306076.1; = p.R1036S on NM_206886.4) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100159768; called by muse, mutect2, varscan2
- CCDC198 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1168515573; called by muse, mutect2, varscan2
- CCDC22 | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 127/361 reads (35%) | catalogued as COSV100873098; called by muse, mutect2, varscan2
- CCDC38 | c.1162C>A p.L388I | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV60182714; called by muse, mutect2, varscan2
- CCDC42 | c.190-1G>T p.X64_splice | Splice Site (SNP) | VAF 72/225 reads (32%) | catalogued as COSV53449669; called by muse, mutect2, varscan2
- CCDC60 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765198651, COSV59548439; called by muse, mutect2, varscan2
- CCDC65 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as COSV56739835; called by muse, mutect2, varscan2
- CCDC7 | c.3628G>T p.D1210Y | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1565692307, COSV56536820; called by muse, mutect2, varscan2
- CCDC82 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758564028, COSV53595057; called by muse, mutect2, varscan2
- CCDC87 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs757299843; called by muse, mutect2, varscan2
- CCDC88A | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as rs756015944, COSV55063921; called by muse, mutect2, varscan2
- CCKAR | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV55162131; called by muse, mutect2, varscan2
- CCL3 | c.63C>A p.F21L | Missense Mutation (SNP) | VAF 172/466 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs536802779; called by muse, mutect2, varscan2
- CCN1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.065); catalogued as rs1194219270; called by muse, mutect2, varscan2
- CCN4 | c.642G>T p.R214S | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99136994; called by muse, mutect2, varscan2
- CCNB3 | c.1515G>T p.K505N | Missense Mutation (SNP) | VAF 90/217 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV52076727; called by muse, mutect2, varscan2
- CCNJL | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs199835106; called by muse, mutect2, varscan2
- CCNL1 | c.1154G>T p.R385I | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV55819193; called by muse, mutect2, varscan2
- CCNYL1 | c.586C>T p.R196C (on ENST00000295414 / NM_001330218.2; = p.R126C on NM_152523.2) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs1217839974, COSV54942097; called by muse, mutect2, varscan2
- CCT6B | c.953G>T p.R318I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58488189; called by muse, mutect2, varscan2
- CD163 | c.2374G>T p.E792* | Nonsense Mutation (SNP) | VAF 117/305 reads (38%) | catalogued as COSV63129466; called by muse, mutect2, varscan2
- CD163L1 | c.1012C>A p.L338I | Missense Mutation (SNP) | VAF 135/363 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV100550263; called by muse, mutect2, varscan2
- CD2AP | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 83/226 reads (37%) | catalogued as COSV100830653; called by muse, mutect2, varscan2
- CD3D | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 148/385 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as rs758839719, COSV52674885; called by muse, mutect2, varscan2
- CD4 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 200/513 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as rs373415505; called by muse, mutect2, varscan2
- CD40LG | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as CM962550; called by muse, mutect2
- CD44 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 135/311 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs776274622, COSV53532537; called by muse, mutect2, varscan2
- CDADC1 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV51911319; called by muse, mutect2
- CDC123 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772028466, COSV55397709; called by muse, mutect2, varscan2
- CDC14C | c.1246G>A p.E416K (on ENST00000428251; = p.E309K on NM_152627.3) | Missense Mutation (SNP) | VAF 126/520 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774990115; called by muse, varscan2
- CDC14C | c.1567C>A p.L523I (on ENST00000428251; = p.L416I on NM_152627.3) | Missense Mutation (SNP) | VAF 60/568 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.055); catalogued as rs1324678283; called by muse, mutect2, varscan2
- CDC23 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1413455263; called by muse, mutect2, varscan2
- CDC7 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs375702482, COSV52309241, COSV99319834; called by muse, mutect2, varscan2
- CDH18 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs370630427; called by muse, mutect2, varscan2
- CDHR1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 102/292 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs201649854; called by muse, mutect2, varscan2
- CDHR3 | c.456C>A p.F152L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.021); catalogued as rs756611741, COSV100488757; called by muse, mutect2, varscan2
- CDHR4 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 88/275 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58526970; called by muse, mutect2, varscan2
- CDK12 | c.3637C>A p.L1213I | Missense Mutation (SNP) | VAF 181/479 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV101420484; called by muse, mutect2, varscan2
- CDK19 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 79/157 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0.34); catalogued as rs953895657; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 184/480 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as rs764066941, COSV62578296; called by muse, mutect2, varscan2
- CDRT1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 144/381 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs113130850; called by muse, mutect2, varscan2
- CDX1 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.207); catalogued as COSV51568386; called by muse, mutect2, varscan2
- CELF6 | c.1370T>C p.M457T | Missense Mutation (SNP) | VAF 121/341 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs765370247; called by muse, mutect2, varscan2
- CEMIP | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 233/613 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs773990711, COSV54996628; called by muse, mutect2, varscan2
- CENPE | c.3140C>A p.S1047Y | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54379591; called by muse, mutect2, varscan2
- CENPJ | c.3035G>T p.R1012I | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV67883240; called by muse, mutect2, varscan2
- CENPT | c.1002G>T p.E334D | Missense Mutation (SNP) | VAF 165/486 reads (34%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.828); catalogued as rs1469428944; called by muse, mutect2, varscan2
- CEP104 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 90/222 reads (41%) | catalogued as rs778850368, COSV65517349; called by muse, mutect2
- CEP162 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 107/316 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs1396392586; called by muse, mutect2, varscan2
- CEP170B | c.1486C>T p.R496C (on ENST00000453495; = p.R425C on NM_015005.3) | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1463812428, COSV69026138; called by muse, mutect2, varscan2
- CEP250 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs774715998; called by muse, mutect2, varscan2
- CEP350 | c.2471G>A p.R824H | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs756890824, COSV100855297; called by muse, mutect2, varscan2
- CEP57 | c.1273-1G>A p.X425_splice | Splice Site (SNP) | VAF 75/244 reads (31%) | catalogued as rs1286851349; called by muse, varscan2
- CEP85 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs187115380, COSV53328707; called by muse, mutect2, varscan2
- CEP85L | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as rs1215374046; called by muse, mutect2
- CES5A | c.810C>T p.D270= | Splice Region (SNP) | VAF 74/181 reads (41%) | catalogued as rs201974680; called by muse, mutect2, varscan2
- CFAP206 | c.1830G>T p.E610D | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as COSV65809033; called by muse, mutect2, varscan2
- CFAP46 | c.6568C>T p.P2190S | Missense Mutation (SNP) | VAF 78/228 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs1464921133; called by muse, mutect2, varscan2
- CFAP53 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 105/275 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs550993731, COSV68351359; called by muse, mutect2, varscan2
- CFAP54 | c.2744G>T p.R915L | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs763606810, COSV101598532; called by muse, mutect2, varscan2
- CFAP54 | c.4699G>T p.E1567* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV61574419; called by muse, mutect2, varscan2
- CFAP57 | c.2647C>T p.R883W | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.782); catalogued as rs1454296376; called by muse, mutect2, varscan2
- CFAP97D1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs772352500; called by muse, mutect2, varscan2
- CFHR3 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 96/129 reads (74%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.943); catalogued as COSV66402707; called by muse, mutect2, varscan2
- CHD1L | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.071); catalogued as rs781862870; called by muse, mutect2, varscan2
- CHD3 | c.3577C>T p.R1193* | Nonsense Mutation (SNP) | VAF 185/500 reads (37%) | catalogued as rs762693054, COSV57877198; called by muse, mutect2, varscan2
- CHEK1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753180922, COSV99629778; called by muse, varscan2
- CHL1 | c.3079C>A p.L1027I (on ENST00000397491 / NM_001253387.1; = p.L1043I on NM_006614.4) | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV56594707; called by muse, mutect2, varscan2
- CHL1 | c.3388G>T p.D1130Y (on ENST00000397491 / NM_001253387.1; = p.D1146Y on NM_006614.4) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56597894; called by muse, mutect2, varscan2
- CHRM2 | c.412A>C p.K138Q | Missense Mutation (SNP) | VAF 105/275 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV57766705; called by muse, mutect2, varscan2
- CHRNA1 | c.1087G>A p.D363N (on ENST00000261007 / NM_001039523.3; = p.D338N on NM_000079.4) | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV53681480; called by muse, varscan2
- CHRNA10 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 186/541 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185752920; called by muse, mutect2, varscan2
- CHRNE | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 53/463 reads (11%) | catalogued as COSV53417587; called by muse, mutect2, varscan2
- CHST7 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 133/343 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52100084; called by muse, mutect2, varscan2
- CIC | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.625); catalogued as rs750968450; called by muse, mutect2, varscan2
- CILP | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 122/313 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs775699319; called by muse, mutect2, varscan2
- CLASP2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751344715; called by muse, mutect2, varscan2
- CLCN1 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 172/477 reads (36%) | catalogued as CM076098, COSV58367166; called by muse, mutect2, varscan2
- CLCN5 | c.1559C>A p.S520Y | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56583787; called by muse, mutect2, varscan2
- CLIC2 | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58936258; called by muse, mutect2, varscan2
- CLSTN2 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756136789, COSV71723435; called by muse, mutect2, varscan2
- CMYA5 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs374313124, COSV71409406; called by muse, mutect2, varscan2
- CMYA5 | c.3611T>C p.V1204A | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.365); catalogued as rs1561207961; called by muse, mutect2, varscan2
- CMYA5 | c.8002G>T p.D2668Y | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as rs377060043; called by muse, mutect2, varscan2
- CNOT2 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1050869264; called by muse, mutect2, varscan2
- CNTN5 | c.1456C>A p.Q486K | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV54362432; called by muse, mutect2, varscan2
- CNTNAP5 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1200791938; called by muse, mutect2
- CNTRL | c.3172C>T p.R1058* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as rs774996573, COSV53050171; called by muse, mutect2, varscan2
- COG6 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 128/308 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.169); catalogued as rs751000285, COSV62995144; called by muse, mutect2, varscan2
- COG6 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 121/317 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs766555956; called by muse, mutect2, varscan2
- COL11A1 | c.5053G>T p.D1685Y | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62173972; called by muse, mutect2, varscan2
- COL11A2 | c.2887G>T p.E963* (on ENST00000341947 / NM_080680.3; = p.E856* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 120/396 reads (30%) | catalogued as COSV59499373; called by muse, varscan2
- COL24A1 | c.3299C>T p.P1100L | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.688); catalogued as rs765411309, COSV100992967; called by muse, mutect2, varscan2
- COL2A1 | c.4051G>T p.E1351* | Nonsense Mutation (SNP) | VAF 176/495 reads (36%) | catalogued as COSV61531911; called by muse, mutect2, varscan2
- COL4A3 | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 181/520 reads (35%) | catalogued as COSV67416263; called by muse, mutect2, varscan2
- COL4A6 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as COSV100563991; called by muse, varscan2
- COL6A5 | c.5776A>C p.N1926H (on ENST00000312481; = p.N1922H on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as rs1198220405; called by muse, mutect2, varscan2
- COL9A1 | c.737G>T p.R246L | Missense Mutation (SNP) | VAF 213/540 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100294698, COSV100294893; called by muse, mutect2, varscan2
- COMMD9 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54672863; called by muse, mutect2
- COMT | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 131/343 reads (38%) | catalogued as COSV52890089; called by muse, mutect2, varscan2
- COPB2 | c.1379G>T p.R460I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100300599; called by muse, mutect2, varscan2
- COPS7B | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 98/326 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV62601498; called by muse, mutect2, varscan2
- COQ10A | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 135/314 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs759099662; called by muse, mutect2, varscan2
- COQ7 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 94/290 reads (32%) | catalogued as rs150938236; called by muse, mutect2, varscan2
- COX15 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 49/410 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462019991, COSV50013585; called by muse, mutect2, varscan2
- COX6C | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as rs376349848, COSV52553206; called by muse, mutect2, varscan2
- CPA4 | c.62T>G p.F21C | Missense Mutation (SNP) | VAF 103/237 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1476324461; called by muse, mutect2, varscan2
- CPA6 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as rs375296440, COSV52725616; called by muse, mutect2, varscan2
- CPD | c.2795G>A p.R932Q | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.943); catalogued as rs1319078793; called by muse, mutect2, varscan2
- CPO | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs762958017; called by muse, mutect2, varscan2
- CPS1 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 34/572 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as rs762550873, COSV99028150; called by muse, mutect2
- CR1 | c.3826C>A p.L1276I | Missense Mutation (SNP) | VAF 85/257 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.641); catalogued as CM1311910; called by muse, mutect2, varscan2
- CR2 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 15/412 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.86); catalogued as rs1216483358; called by muse, mutect2
- CRACD | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 144/347 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1407907307, COSV51718305; called by muse, mutect2, varscan2
- CRY2 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV101314567; called by muse, mutect2, varscan2
- CRYBG3 | c.6210C>A p.F2070L | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs769992914; called by muse, varscan2
- CSKMT | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs758886851; called by muse, mutect2, varscan2
- CSMD1 | c.3712G>A p.D1238N (on ENST00000520002; = p.D1237N on NM_033225.6) | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.234); catalogued as rs373923214; called by muse, mutect2, varscan2
- CSMD3 | c.10856C>A p.S3619Y (on ENST00000297405 / NM_001363185.1; = p.S3450Y on NM_052900.3) | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV52145829; called by muse, varscan2
- CSMD3 | c.7673A>C p.K2558T (on ENST00000297405 / NM_001363185.1; = p.K2454T on NM_052900.3) | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV99851918; called by muse, mutect2
- CSNK1E | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs1569084268, COSV63290718; called by muse, mutect2, varscan2
- CSNK2A3 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 205/456 reads (45%) | catalogued as rs527645267; called by muse, mutect2, varscan2
- CSPG4 | c.6739C>T p.R2247* | Nonsense Mutation (SNP) | VAF 39/101 reads (39%) | catalogued as rs777249049, COSV57889753; called by muse, mutect2, varscan2
- CSPP1 | c.1708G>A p.D570N (on ENST00000676605; = p.D529N on NM_024790.6) | Missense Mutation (SNP) | VAF 152/436 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs773480768, COSV51581910; called by muse, mutect2, varscan2
- CSPP1 | c.3773C>T p.S1258L (on ENST00000676605; = p.S1217L on NM_024790.6) | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs768228167, COSV51593356; called by muse, mutect2
- CSTF3 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV60613102; called by muse, mutect2, varscan2
- CTNNA1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as rs781520852, COSV57074199; called by muse, mutect2, varscan2
- CTNNA2 | c.2816C>T p.S939L (on ENST00000402739 / NM_001282597.3; = p.S891L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1052098013, COSV58132864; called by muse, mutect2, varscan2
- CTNNAL1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as rs1248520632; called by muse, mutect2, varscan2
- CTNND2 | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 97/278 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58913197; called by muse, mutect2, varscan2
- CUBN | c.4471G>A p.D1491N | Missense Mutation (SNP) | VAF 170/426 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs763162385, COSV64719380; called by muse, mutect2, varscan2
- CUL1 | c.2017C>A p.L673I | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.149); catalogued as COSV57386597; called by muse, mutect2, varscan2
- CUL3 | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 55/131 reads (42%) | catalogued as COSV52361645; called by muse, mutect2, varscan2
- CUL4B | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV60685767; called by muse, mutect2
- CUL4B | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 82/225 reads (36%) | catalogued as CM151182, COSV60689694; called by muse, mutect2, varscan2
- CUL4B | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 73/223 reads (33%) | catalogued as COSV60685793; called by muse, mutect2, varscan2
- CWF19L2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs769476939, COSV56521707; called by muse, mutect2, varscan2
- CXCL9 | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV99345747, COSV99345831; called by muse, mutect2
- CYB5R1 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768976568, COSV100924874; called by muse, mutect2, varscan2
- CYB5R4 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs1012959984, COSV63747053; called by muse, mutect2, varscan2
- CYLC1 | c.1154G>T p.R385I | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV61410335, COSV61412475; called by muse, mutect2, varscan2
- CYP26B1 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 206/557 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs752223643, COSV50010601; called by muse, mutect2, varscan2
- CYP39A1 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201855604, COSV51494975; called by muse, mutect2, varscan2
- CYP3A4 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV100316008, COSV60502547; called by muse, mutect2, varscan2
- CYP4A22 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs780190981, COSV53737797; called by muse, mutect2, varscan2
- CYP4Z1 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs756404977, COSV61965094; called by muse, mutect2, varscan2
- CYP7A1 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 173/493 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs776916391, COSV56965238; called by muse, mutect2, varscan2
- CYP7B1 | c.1517C>A p.S506Y | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59582175; called by muse, mutect2, varscan2
- DARS2 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 163/430 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as rs776225606; called by muse, mutect2, varscan2
- DCAF6 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as COSV56576511; called by muse, mutect2, varscan2
- DCAF8L2 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs777466794, COSV70551102; called by muse, mutect2, varscan2
- DCBLD1 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 116/285 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143761981; called by muse, mutect2, varscan2
- DCC | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 223/532 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200830938; called by muse, mutect2, varscan2
- DCHS1 | c.6095G>A p.R2032Q | Missense Mutation (SNP) | VAF 137/366 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs762866278; called by muse, mutect2, varscan2
- DCHS2 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs565018645, COSV59726788; called by muse, mutect2, varscan2
- DCLK1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 101/269 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1366698690, COSV55170182; called by muse, mutect2, varscan2
- DCLK1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 133/313 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV55171740; called by muse, mutect2, varscan2
- DCST1 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 14/402 reads (3%) | catalogued as COSV99791917; called by muse, mutect2
- DCT | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 65/574 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs762745612, COSV65468238, COSV65468438; called by muse, mutect2, varscan2
- DDC | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 63/618 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764694805; called by muse, mutect2, varscan2
- DDIAS | c.1020C>A p.F340L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV100231001; called by muse, mutect2, varscan2
- DDO | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 107/273 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs1476037057; called by muse, mutect2, varscan2
- DDX5 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as rs1555670894, COSV56749006; called by muse, mutect2, varscan2
- DDX53 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100029035, COSV60069618; called by muse, mutect2, varscan2
- DDX60L | c.4251G>T p.K1417N | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs959745035, COSV99488751; called by muse, mutect2, varscan2
- DEDD2 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 108/247 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs374131947; called by muse, mutect2, varscan2
- DENND2A | c.1395C>A p.F465L | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52046974, COSV52053714, COSV99326088; called by muse, mutect2, varscan2
- DENND2A | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs760125345; called by muse, mutect2, varscan2
- DENND2C | c.1373G>A p.R458H (on ENST00000393274 / NM_001256404.2; = p.R401H on NM_198459.4) | Missense Mutation (SNP) | VAF 126/328 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs200716799, COSV101283926; called by muse, mutect2, varscan2
- DENND2C | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as rs760314015, COSV101283961; called by muse, mutect2, varscan2
- DENND3 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52800541; called by muse, mutect2, varscan2
- DEUP1 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.843); catalogued as COSV99977251; called by muse, mutect2, varscan2
- DGKI | c.2436A>T p.E812D | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs779988185; called by muse, varscan2
- DGKI | c.682-1G>T p.X228_splice | Splice Site (SNP) | VAF 51/134 reads (38%) | catalogued as COSV99937933; called by muse, mutect2, varscan2
- DHRS2 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs756989511; called by muse, mutect2
- DHX9 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as rs865830988, COSV62358500; called by muse, mutect2, varscan2
- DIAPH2 | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 46/106 reads (43%) | catalogued as COSV100236169, COSV61268693; called by muse, varscan2
- DIAPH3 | c.1915G>T p.E639* (on ENST00000400324 / NM_001042517.2; = p.E376* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 40/120 reads (33%) | catalogued as COSV57375034; called by muse, varscan2
- DIP2C | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV55179147; called by muse, mutect2, varscan2
- DISC1 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201902199, COSV54411258; called by muse, mutect2, varscan2
- DKC1 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs200438009; called by muse, mutect2, varscan2
- DKK4 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as rs772507402, COSV55182146; called by muse, mutect2, varscan2
- DLG2 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 100/311 reads (32%) | catalogued as COSV65843667; called by muse, mutect2, varscan2
- DLGAP2 | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs765818847, COSV70100451; called by muse, mutect2, varscan2
- DLGAP5 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as COSV55961983, COSV55965303; called by muse, mutect2, varscan2
- DMBT1 | c.5131G>A p.E1711K (on ENST00000338354 / NM_001377530.1; = p.E954K on NM_004406.3) | Missense Mutation (SNP) | VAF 274/785 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748445351, COSV57544722; called by muse, mutect2, varscan2
- DMGDH | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 114/306 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs537451670, COSV54860381; called by muse, varscan2
- DMTF1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 103/282 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1447694429; called by muse, mutect2, varscan2
- DMXL2 | c.4253G>A p.R1418Q | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as rs755717597; called by muse, mutect2, varscan2
- DNA2 | c.3037C>A p.L1013I | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV64430476; called by muse, mutect2, varscan2
- DNAH10 | c.4477G>A p.E1493K (on ENST00000409039; = p.E1432K on NM_207437.3) | Missense Mutation (SNP) | VAF 139/366 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs373563221, COSV68989561; called by muse, mutect2, varscan2
- DNAH10 | c.6634G>A p.E2212K (on ENST00000409039; = p.E2151K on NM_207437.3) | Missense Mutation (SNP) | VAF 25/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68987781; called by muse, mutect2
- DNAH10 | c.7127A>G p.N2376S (on ENST00000409039; = p.N2315S on NM_207437.3) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as rs745672538; called by muse, mutect2
- DNAH10 | c.9243G>T p.K3081N (on ENST00000409039; = p.K3020N on NM_207437.3) | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV68988915; called by muse, mutect2
- DNAH11 | c.10521G>T p.K3507N | Missense Mutation (SNP) | VAF 86/247 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100179764; called by muse, mutect2, varscan2
- DNAH12 | c.2698G>T p.E900* (on ENST00000351747; = p.E923* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100696574; called by muse, mutect2
- DNAH3 | c.2559G>T p.K853N | Missense Mutation (SNP) | VAF 89/236 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.26); catalogued as rs1241652858; called by muse, mutect2, varscan2
- DNAH5 | c.3784G>T p.E1262* | Nonsense Mutation (SNP) | VAF 96/262 reads (37%) | catalogued as COSV54210192, COSV54243654; called by muse, mutect2, varscan2
- DNAH7 | c.119G>T p.R40I | Missense Mutation (SNP) | VAF 79/216 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV100414225; called by muse, mutect2, varscan2
- DNAH8 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.03); catalogued as rs772099828, COSV100545525; called by muse, mutect2, varscan2
- DNAH8 | c.2705A>T p.D902V | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as rs755414582; called by muse, mutect2, varscan2
- DNAH8 | c.8557A>G p.T2853A | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1317264025; called by muse, mutect2, varscan2
- DNAH8 | c.11600C>A p.S3867Y | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100543381, COSV59432925; called by muse, mutect2
- DNAH9 | c.4783G>A p.D1595N | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs780836548, COSV52365436; called by muse, mutect2, varscan2
- DNAH9 | c.11105C>A p.S3702Y | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52340571; called by muse, mutect2
- DNAI3 | c.1902C>A p.F634L | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV54001464, COSV54002599; called by muse, mutect2, varscan2
- DNAI4 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs949497667, COSV64021802; called by muse, mutect2, varscan2
- DNAJB13 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs535916675; called by muse, mutect2, varscan2
- DNAJB6 | c.65+1G>A p.X22_splice | Splice Site (SNP) | VAF 54/149 reads (36%) | catalogued as COSV51094165; called by muse, mutect2, varscan2
- DNAJC10 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 26/101 reads (26%) | catalogued as COSV51136266; called by muse, varscan2
- DNAJC13 | c.5336C>A p.S1779Y | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV53450232; called by muse, mutect2, varscan2
- DNAJC14 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs774254718, COSV57912056; called by muse, mutect2, varscan2
- DNAJC28 | c.1145T>G p.F382C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV58721187; called by muse, mutect2, varscan2
- DNAJC6 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs779000495; called by muse, mutect2
- DNM1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1007751329; called by muse, mutect2, varscan2
- DOCK7 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs573187574; called by muse, mutect2, varscan2
- DOCK8 | c.3430G>A p.A1144T | Missense Mutation (SNP) | VAF 34/574 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs1030455029, COSV66621040, COSV66624321; called by muse, mutect2
- DPF3 | c.751G>T p.G251* | Nonsense Mutation (SNP) | VAF 72/183 reads (39%) | catalogued as rs1434192538; called by muse, mutect2, varscan2
- DPPA2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs780208223, COSV72117932; called by muse, mutect2, varscan2
- DPY19L2 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 145/338 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780447672, COSV61043421; called by muse, mutect2, varscan2
- DPYS | c.1155T>G p.I385M | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59827055; called by muse, varscan2
- DPYSL5 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 60/209 reads (29%) | catalogued as COSV56511289; called by muse, mutect2, varscan2
- DRP2 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV100871909; called by muse, mutect2, varscan2
- DSC3 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as COSV64571502; called by muse, mutect2, varscan2
- DSCAM | c.5785T>G p.L1929V | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.138); catalogued as rs1164310702; called by muse, mutect2, varscan2
- DSE | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs369887455; called by muse, mutect2, varscan2
- DSEL | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59490458, COSV59492081; called by muse, mutect2, varscan2
- DSEL | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.325); catalogued as COSV59490624; called by muse, mutect2, varscan2
- DSG2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs532305326, COSV55200041; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.4825G>A p.A1609T | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1444350092; called by muse, mutect2, varscan2
- DSPP | c.981G>T p.E327D | Missense Mutation (SNP) | VAF 118/280 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.136); catalogued as rs778282028, COSV56808531; called by muse, mutect2, varscan2
- DST | c.12628C>T p.R4210C (on ENST00000361203 / NM_001374722.1; = p.R1798C on NM_015548.5) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1000717078; called by muse, mutect2, varscan2
- DST | c.341G>T p.R114I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56801509; called by muse, mutect2, varscan2
- DTNB | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 177/414 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs768951661, COSV56480745; called by muse, mutect2, varscan2
- DUSP10 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 19/242 reads (8%) | catalogued as COSV60456963; called by muse, mutect2
- DUSP4 | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.352); catalogued as COSV53546694; called by muse, mutect2, varscan2
- DYNC1H1 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 316/773 reads (41%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.638); catalogued as COSV100794736; called by muse, mutect2, varscan2
- DYNC2H1 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs561232842, COSV62086954; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYRK1A | c.1274A>C p.N425T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs777063595; called by muse, varscan2
- DYRK1A | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 104/277 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); catalogued as rs1381541764; called by muse, mutect2, varscan2
- DYRK1B | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 139/395 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV55683302; called by muse, mutect2, varscan2
- DZIP3 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV64314010; called by muse, varscan2
- DZIP3 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs1391719670, COSV64311263; called by muse, mutect2, varscan2
- E2F1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 186/504 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs864622017, COSV58534885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECSIT | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 168/541 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373672064; called by muse, mutect2, varscan2
- ECT2L | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs754540928, COSV62882962; called by muse, mutect2, varscan2
- EDC4 | c.3095C>T p.S1032L | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as rs746048856, COSV59303245; called by muse, mutect2, varscan2
- EDIL3 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs375171867; called by muse, mutect2, varscan2
- EEF1A1 | c.125T>G p.F42C | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100303345; called by muse, mutect2, varscan2
- EFCAB5 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.089); catalogued as rs1184427807; called by muse, mutect2, varscan2
- EGFLAM | c.2770C>T p.R924W (on ENST00000354891 / NM_001205301.2; = p.R916W on NM_152403.4) | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs550711191, COSV59298072; called by muse, mutect2, varscan2
- EHD3 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59032778; called by muse, mutect2, varscan2
- EIF3I | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100557235; called by muse, mutect2, varscan2
- EIF3L | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs760820592, COSV67739557; called by muse, mutect2, varscan2
- EIF4G1 | c.935G>A p.R312H (on ENST00000346169 / NM_198241.3; = p.R116H on NM_004953.5) | Missense Mutation (SNP) | VAF 135/365 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs754009820, COSV59990810; called by muse, mutect2, varscan2
- ELAPOR2 | c.2221G>T p.E741* (on ENST00000450689 / NM_001142749.3; = p.E574* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 88/202 reads (44%) | catalogued as rs557781112, COSV51885969, COSV51891823; called by muse, mutect2, varscan2
- ELF2 | c.1165C>T p.R389C (on ENST00000379550 / NM_001331036.2; = p.R329C on NM_006874.4) | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs754750921, COSV99642646; called by muse, mutect2, varscan2
- ELL | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 75/236 reads (32%) | catalogued as COSV53211399; called by muse, mutect2, varscan2
- ELMOD1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs752553992, COSV56191383; called by muse, mutect2, varscan2
- ELOA3D | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 115/2548 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs757374148; called by muse, mutect2
- ELSPBP1 | c.342C>A p.F114L | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV60413049; called by muse, mutect2, varscan2
- EML5 | c.5822G>A p.R1941Q (on ENST00000380664; = p.R1949Q on NM_183387.3) | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369350892; called by muse, mutect2, varscan2
- ENOSF1 | c.681G>T p.E227D (on ENST00000340116 / NM_001354066.2; = p.E179D on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/292 reads (43%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.978); catalogued as COSV99200947; called by muse, varscan2
- ENOX2 | c.704G>T p.R235I (on ENST00000338144 / NM_001382520.1; = p.R206I on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV57648164; called by muse, mutect2
- ENPEP | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs1437266122, COSV54446763; called by muse, mutect2, varscan2
- EPAS1 | c.1248C>T p.F416= | Splice Region (SNP) | VAF 109/250 reads (44%) | catalogued as rs761886735; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPB41L1 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 131/379 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs754539981, CM142381, COSV52436084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHA4 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 94/219 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV56030623; called by muse, mutect2, varscan2
- EPHA5 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1342407694, COSV56680010; called by muse, mutect2, varscan2
- EPHA5 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 102/235 reads (43%) | catalogued as COSV56633312; called by muse, mutect2, varscan2
- EPHA5 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 78/210 reads (37%) | catalogued as COSV56630678; called by muse, mutect2, varscan2
- EPHX4 | c.957G>T p.K319N | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV64889071; called by muse, mutect2, varscan2
- EPHX4 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1203741019; called by muse, mutect2
- EPS8 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs748350706, COSV99843568; called by muse, mutect2, varscan2
- EQTN | c.293A>C p.K98T | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as rs755495856; called by muse, mutect2, varscan2
- ERICH1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.28); catalogued as rs1314008466; called by muse, mutect2, varscan2
- ERICH5 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 94/214 reads (44%) | catalogued as rs1183167021, COSV59317207; called by muse, mutect2, varscan2
- ERN2 | c.1173G>T p.E391D | Missense Mutation (SNP) | VAF 114/280 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV56837512; called by muse, mutect2, varscan2
- ESPNL | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as rs757311152; called by muse, mutect2, varscan2
- ETV2 | c.785G>A p.W262* | Nonsense Mutation (SNP) | VAF 138/406 reads (34%) | catalogued as rs1483767386; called by muse, mutect2, varscan2
- ETV5 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 131/340 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs757415664, COSV104403184; called by muse, mutect2, varscan2
- EVX2 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 293/768 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1379226242, COSV57962786; called by muse, mutect2, varscan2
- EXD1 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs376831027; called by muse, mutect2, varscan2
- EXPH5 | c.5653G>A p.D1885N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1205042314; called by muse, mutect2, varscan2
- EXT1 | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 195/538 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs753261171; called by muse, mutect2, varscan2
- EYA1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 136/342 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.892); catalogued as rs561111097, CM136180, COSV58171414; called by muse, mutect2, varscan2
- EZH2 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 66/185 reads (36%) | catalogued as CM1312127, COSV57465258; called by muse, mutect2, varscan2
- F5 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV63120327; called by muse, mutect2, varscan2
- FAM110B | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.196); catalogued as rs1467884010, COSV64064448; called by muse, mutect2, varscan2
- FAM114A1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs759121456, COSV62673296; called by muse, mutect2, varscan2
- FAM160A1 | c.2598G>T p.E866D | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); catalogued as rs1187791295, COSV70706512, COSV70706908; called by muse, varscan2
- FAM160A2 | c.2759G>A p.R920Q (on ENST00000449352 / NM_001098794.2; = p.R934Q on NM_032127.4) | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs1416622926; called by muse, mutect2, varscan2
- FAM171A1 | c.1412C>A p.S471Y | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1320801883, COSV65317757; called by muse, mutect2, varscan2
- FAM178B | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 82/397 reads (21%) | catalogued as rs539837703, COSV59971926; called by muse, mutect2, varscan2
- FAM186A | c.6011G>A p.R2004Q | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1057338425, COSV59251089; called by muse, mutect2, varscan2
- FAM71D | c.1192C>A p.L398I | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.049); catalogued as COSV61294949; called by muse, varscan2
- FAM9C | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.728); catalogued as COSV100452848; called by muse, mutect2, varscan2
- FAN1 | c.63G>T p.K21N | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV62951648; called by muse, mutect2, varscan2
- FANCB | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.469); catalogued as rs370199124; called by muse, mutect2, varscan2
- FANCM | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 99/269 reads (37%) | catalogued as rs778176467, COSV57498385; called by muse, mutect2, varscan2
- FASTKD1 | c.2509G>T p.E837* | Nonsense Mutation (SNP) | VAF 46/145 reads (32%) | catalogued as COSV52930805, COSV52931254; called by muse, mutect2, varscan2
- FAT3 | c.1708A>G p.N570D | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs1434938621; called by muse, mutect2, varscan2
- FAT4 | c.14861C>T p.S4954F | Missense Mutation (SNP) | VAF 107/298 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV100628728, COSV58687122; called by muse, mutect2, varscan2
- FBLN7 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553475753, COSV58666010; called by muse, mutect2, varscan2
- FBN1 | c.4943-1G>T p.X1648_splice | Splice Site (SNP) | VAF 93/255 reads (36%) | catalogued as CS157716; called by muse, mutect2, varscan2
- FBN2 | c.6583C>T p.R2195C | Missense Mutation (SNP) | VAF 131/362 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs886059896, COSV52511930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN3 | c.1659C>A p.F553L | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV99561003; called by muse, mutect2, varscan2
- FBN3 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs543293329; called by muse, mutect2, varscan2
- FBXL13 | c.1456T>G p.L486V | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV104399433; called by muse, mutect2, varscan2
- FBXL4 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 154/375 reads (41%) | catalogued as COSV57747033; called by muse, mutect2, varscan2
- FBXO11 | c.2581C>T p.R861* (on ENST00000403359 / NM_001190274.2; = p.R777* on NM_025133.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV52276826; called by muse, mutect2, varscan2
- FBXO39 | c.1205G>T p.R402I | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58621427; called by muse, mutect2, varscan2
- FBXO43 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs780589126, COSV71053675; called by muse, mutect2, varscan2
- FBXO47 | c.1004T>A p.I335N | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751529737; called by muse, mutect2, varscan2
- FBXO8 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 137/389 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs769805068; called by muse, mutect2, varscan2
- FBXW11 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as rs1199148006, COSV51608710; called by muse, mutect2, varscan2
- FCN3 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 155/488 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs745599639, COSV99585314; called by muse, mutect2, varscan2
- FCRL4 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0.251); catalogued as rs774005304, COSV54866696; called by muse, mutect2, varscan2
- FEM1B | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs755637386, COSV60988198; called by muse, mutect2, varscan2
- FER1L6 | c.3142G>A p.E1048K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs200333104, COSV67547702; called by muse, mutect2, varscan2
- FETUB | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.392); catalogued as rs529475246; called by muse, mutect2, varscan2
- FGD5 | c.3940C>T p.R1314W | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs750545408, COSV53236523; called by muse, varscan2
- FGF23 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 248/581 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52975152; called by muse, mutect2, varscan2
- FGF5 | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 121/290 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100427846; called by muse, varscan2
- FIGLA | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60089778; called by muse, mutect2, varscan2
- FILIP1 | c.1380G>T p.K460N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV52733136; called by muse, mutect2
- FKBP15 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 36/133 reads (27%) | catalogued as COSV53039542; called by muse, mutect2, varscan2
- FKBP9 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs757911744; called by muse, mutect2, varscan2
- FLG | c.9974C>A p.S3325Y | Missense Mutation (SNP) | VAF 58/673 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1247954683, COSV100912127; called by muse, mutect2
- FLNA | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 167/450 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.177); catalogued as rs782723195; called by muse, varscan2
- FLNC | c.1090T>G p.F364V | Missense Mutation (SNP) | VAF 225/617 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs764604033; called by muse, mutect2, varscan2
- FLNC | c.3887C>T p.S1296L | Missense Mutation (SNP) | VAF 129/331 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747587140, COSV57949454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT1 | c.2561C>T p.T854M | Missense Mutation (SNP) | VAF 212/605 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs767930948, COSV56718629; called by muse, mutect2, varscan2
- FLT4 | c.3262G>A p.D1088N | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376446971, COSV56106742, COSV99986231; called by muse, mutect2, varscan2
- FMN1 | c.2492A>C p.K831T (on ENST00000616417 / NM_001277313.2; = p.K608T on NM_001103184.4) | Missense Mutation (SNP) | VAF 26/333 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.902); catalogued as COSV57920845; called by muse, mutect2
- FMNL2 | c.2761G>T p.D921Y | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56491833; called by muse, mutect2, varscan2
- FOXD4L6 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs1300152302; called by mutect2, varscan2
- FOXN4 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 148/377 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs551517487; called by muse, mutect2, varscan2
- FOXO1 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs756553520, COSV65427827; called by muse, mutect2, varscan2
- FOXR1 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 190/468 reads (41%) | catalogued as rs782152027, COSV57651440; called by muse, mutect2, varscan2
- FPGT | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs376392962; called by muse, mutect2, varscan2
- FRAS1 | c.3988C>A p.L1330I | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.4); catalogued as rs1281813474; called by muse, mutect2, varscan2
- FREM1 | c.3690G>T p.K1230N | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV66525088; called by muse, mutect2
- FREM2 | c.3991G>A p.D1331N | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54828472, COSV54852530, COSV54855268; called by muse, mutect2
- FRMPD3 | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs1029876070; called by muse, mutect2, varscan2
- FSIP1 | c.1558G>T p.D520Y | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as COSV63223390; called by muse, mutect2, varscan2
- FSIP2 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.58); catalogued as rs564204682; called by muse, mutect2, varscan2
- FSIP2 | c.2507C>A p.S836Y | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as rs1302696501, COSV100556139, COSV58082789; called by muse, mutect2, varscan2
- FSIP2 | c.10097C>A p.S3366Y | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs917017719; called by muse, mutect2, varscan2
- FSIP2 | c.14704G>T p.E4902* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV58096299; called by muse, mutect2, varscan2
- FSIP2 | c.17339G>A p.G5780E | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); catalogued as COSV58089463; called by muse, mutect2, varscan2
- FSIP2 | c.19105G>T p.D6369Y | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs777496327, COSV58083067; called by muse, mutect2, varscan2
- FUT10 | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 98/250 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV59453103; called by muse, mutect2, varscan2
- FYTTD1 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs779562426, COSV99611582; called by muse, mutect2, varscan2
- G2E3 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.165); catalogued as rs763733235, COSV52839820; called by muse, mutect2, varscan2
- G3BP2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs765465830, COSV62977156; called by muse, mutect2, varscan2
- GAA | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 123/330 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs760063214, HM090033, COSV56407220; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABARAP | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 109/281 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV100020965; called by muse, mutect2, varscan2
- GABRA1 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 114/305 reads (37%) | catalogued as COSV50098462, COSV50111407; called by muse, mutect2, varscan2
- GABRA3 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV64794720; called by muse, mutect2, varscan2
- GABRB3 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 128/327 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as rs766672883, COSV100158514, COSV54670778; called by muse, mutect2, varscan2
- GABRE | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 111/277 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.322); catalogued as COSV64819609; called by muse, mutect2, varscan2
- GALC | c.622-1G>T p.X208_splice | Splice Site (SNP) | VAF 32/214 reads (15%) | catalogued as CS971740; called by muse, mutect2, varscan2
- GALNS | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 233/587 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761043390, COSV51939367; called by muse, mutect2, varscan2
- GALNT1 | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as rs749687300, COSV52455121; called by muse, mutect2, varscan2
- GALNT14 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs148126284; called by muse, varscan2
- GALNT5 | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763921291, COSV52036710; called by muse, mutect2, varscan2
- GALNT7 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.022); catalogued as rs748069163, COSV53934319; called by muse, mutect2, varscan2
- GALNT8 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52897342; called by muse, mutect2, varscan2
- GALNT8 | c.1594-1G>T p.X532_splice | Splice Site (SNP) | VAF 16/48 reads (33%) | catalogued as rs11063332; called by mutect2, varscan2
- GALNTL5 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 123/295 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV67179427; called by muse, mutect2, varscan2
- GANC | c.1793C>A p.S598Y | Missense Mutation (SNP) | VAF 82/214 reads (38%) | PolyPhen probably damaging (0.997); catalogued as COSV100530902; called by muse, mutect2, varscan2
- GAP43 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751087225, COSV59344154, COSV59346415; called by muse, mutect2, varscan2
- GBGT1 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs1335402262, COSV100923785; called by muse, mutect2, varscan2
- GBP4 | c.1362G>T p.K454N | Missense Mutation (SNP) | VAF 117/322 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.821); catalogued as COSV63252951; called by muse, mutect2, varscan2
- GBP6 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs776753385; called by muse, mutect2, varscan2
- GBP6 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as rs775373620; called by muse, mutect2, varscan2
- GDI1 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 183/504 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV50130919; called by muse, mutect2, varscan2
- GEMIN4 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs377598346; called by muse, mutect2, varscan2
- GEMIN5 | c.3140T>G p.L1047* | Nonsense Mutation (SNP) | VAF 129/302 reads (43%) | catalogued as rs961763433; called by muse, varscan2
- GEMIN7 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 109/357 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs745702182, COSV54319391; called by muse, mutect2, varscan2
- GFPT2 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.552); catalogued as rs750170076; called by muse, varscan2
- GFRA1 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 104/305 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1167037752, COSV100816097; called by muse, mutect2, varscan2
- GGCX | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 218/592 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.061); catalogued as rs771694780; called by muse, mutect2, varscan2
- GGNBP2 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as rs963224918; called by muse, mutect2
- GINM1 | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV100805294; called by muse, mutect2, varscan2
- GJA10 | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.443); catalogued as COSV101005298; called by muse, mutect2, varscan2
- GJA9 | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 105/348 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs1347390543; called by muse, varscan2
- GK2 | c.1495C>A p.R499S | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.375); catalogued as COSV62626492; called by muse, mutect2, varscan2
- GLP2R | c.1016T>G p.I339S | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1361701890; called by muse, mutect2, varscan2
- GLT6D1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 59/160 reads (37%) | catalogued as rs771898457, COSV65628375; called by muse, mutect2, varscan2
- GNMT | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 265/696 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs936866741, COSV55101990; called by muse, mutect2, varscan2
- GOLGA5 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 88/273 reads (32%) | catalogued as COSV50832207; called by muse, mutect2, varscan2
- GOLM1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV57415322; called by muse, mutect2, varscan2
- GOLM2 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 9/114 reads (8%) | catalogued as COSV55461368; called by muse, mutect2
- GOT1L1 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs802168; called by muse, mutect2, varscan2
- GOT1L1 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs915251163; called by muse, varscan2
- GP9 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 183/452 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.2); catalogued as rs765620037, COSV56623836; called by muse, mutect2, varscan2
- GPLD1 | c.767T>G p.F256C | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1259796340; called by muse, mutect2, varscan2
- GPR149 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV101078658, COSV67670597; called by muse, mutect2, varscan2
- GPR155 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 47/116 reads (41%) | catalogued as COSV55038287; called by muse, mutect2, varscan2
- GPR155 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as rs146408702; called by muse, varscan2
- GPR158 | c.1581G>T p.M527I | Missense Mutation (SNP) | VAF 125/356 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV66277596; called by muse, mutect2, varscan2
- GPR174 | c.780A>C p.E260D | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV52135096; called by muse, mutect2, varscan2
- GPR20 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 104/329 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs751575687; called by muse, mutect2, varscan2
- GPR78 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs201411082, COSV101223907; called by muse, mutect2, varscan2
- GPR82 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 39/339 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as rs368375953, COSV56887174; called by muse, mutect2, varscan2
- GPR83 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 140/375 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99703615; called by muse, mutect2, varscan2
- GPRC6A | c.2333A>G p.Y778C | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1475567340; called by muse, mutect2, varscan2
- GPRC6A | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs375283736, COSV59955091; called by muse, mutect2, varscan2
- GRB14 | c.744G>T p.K248N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55741034; called by muse, varscan2
- GREB1L | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs569521616, COSV52560173; called by muse, mutect2, varscan2
- GRID1 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 19/247 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs909889718; called by muse, mutect2
- GRIK3 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 77/378 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745894431, COSV104426702; called by muse, mutect2, varscan2
- GRIK4 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 147/392 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV70802310; called by muse, mutect2, varscan2
- GRIK4 | c.2265C>T p.V755= | Splice Region (SNP) | VAF 54/115 reads (47%) | catalogued as rs770274217, COSV101483534; called by muse, mutect2, varscan2
- GRIN3A | c.2080C>A p.L694M | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62458784; called by muse, mutect2, varscan2
- GRIPAP1 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782643265, COSV64551667; called by muse, mutect2, varscan2
- GRK3 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60794949; called by muse, mutect2, varscan2
- GRM1 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs112775415, COSV51137407; called by muse, mutect2, varscan2
- GRM2 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs759568400; called by muse, mutect2, varscan2
- GRM3 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.883); catalogued as rs1355501473; called by muse, mutect2, varscan2
- GRM7 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 138/368 reads (38%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.974); catalogued as COSV100738599, COSV63130639, COSV63139535; called by muse, mutect2, varscan2
- GRM8 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.734); catalogued as rs758371200, COSV58804439; called by muse, mutect2
- GRXCR1 | c.18G>T p.M6I | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV67671805; called by muse, mutect2, varscan2
- GSC | c.749A>G p.K250R | Missense Mutation (SNP) | VAF 137/592 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV53077766; called by mutect2, varscan2
- GSDME | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 186/572 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs1298708411, COSV61652401, COSV61652647; called by muse, mutect2, varscan2
- GTF2H2 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99174111; called by muse, mutect2, varscan2
- GUCY2C | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149347801; called by muse, mutect2, varscan2
- GYS2 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 123/324 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53926018; called by muse, mutect2, varscan2
- HACE1 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 98/250 reads (39%) | catalogued as COSV53504619; called by muse, mutect2, varscan2
- HAPLN1 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV57150323; called by muse, mutect2, varscan2
- HARS2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 163/474 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.611); catalogued as rs1229581230, COSV51226900; called by muse, mutect2, varscan2
- HAS1 | c.1242C>A p.F414L | Missense Mutation (SNP) | VAF 213/580 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV55788427; called by muse, mutect2, varscan2
- HBD | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 231/624 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as COSV53082793; called by muse, mutect2, varscan2
- HCN1 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV57493557; called by muse, mutect2, varscan2
- HEATR1 | c.1704G>T p.K568N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV63980728; called by muse, mutect2, varscan2
- HEATR5B | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51855711; called by muse, mutect2, varscan2
- HECA | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); catalogued as rs1448043668; called by muse, mutect2, varscan2
- HECW2 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); catalogued as rs764980123, COSV53655313, COSV53671757; called by muse, mutect2, varscan2
- HELLS | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs372532589; called by muse, mutect2, varscan2
- HEMGN | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 39/125 reads (31%) | catalogued as COSV52325860, COSV99412447; called by muse, mutect2, varscan2
- HEMGN | c.80-1G>T p.X27_splice | Splice Site (SNP) | VAF 70/157 reads (45%) | catalogued as COSV52327806; called by muse, mutect2, varscan2
- HENMT1 | c.542A>G p.H181R | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472833370; called by muse, mutect2, varscan2
- HEPACAM2 | c.1289C>T p.S430F (on ENST00000394468 / NM_001039372.4; = p.S418F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59061234; called by muse, mutect2, varscan2
- HERC1 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1267494510, COSV71247085, COSV71249758; called by muse, mutect2, varscan2
- HGF | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 101/250 reads (40%) | catalogued as COSV55950843; called by muse, mutect2, varscan2
- HIBCH | c.1133C>A p.S378Y | Missense Mutation (SNP) | VAF 106/320 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs774513879, COSV61410077; called by muse, mutect2, varscan2
- HIPK1 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 169/437 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs370415621, COSV61245810; called by muse, mutect2, varscan2
- HIPK3 | c.3022G>A p.D1008N | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs200039689; called by muse, mutect2, varscan2
- HIVEP2 | c.1421C>A p.P474H | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99174807; called by muse, mutect2, varscan2
- HLA-DOB | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 178/490 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755078086, COSV71270862; called by muse, mutect2, varscan2
- HMCN1 | c.7203G>T p.K2401N | Missense Mutation (SNP) | VAF 112/316 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs775621788, COSV54919428; called by muse, mutect2, varscan2
- HMCN1 | c.9135G>T p.K3045N | Missense Mutation (SNP) | VAF 111/288 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs755893317; called by muse, mutect2, varscan2
- HNMT | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as rs1037864915; called by muse, mutect2, varscan2
- HNRNPUL2 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1365417868, COSV100079502; called by muse, mutect2, varscan2
- HOMER1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 68/174 reads (39%) | catalogued as COSV56524019; called by muse, mutect2, varscan2
- HOXA4 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 131/361 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57825200; called by muse, mutect2, varscan2
- HOXD9 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 85/189 reads (45%) | catalogued as COSV50892276; called by muse, mutect2, varscan2
- HPGDS | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 12/162 reads (7%) | catalogued as COSV99756058; called by muse, mutect2
- HRH1 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as rs779343203, COSV67955057, COSV67955813; called by muse, mutect2, varscan2
- HSD17B2 | c.1094G>T p.R365I | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs756891308; called by muse, mutect2, varscan2
- HSPG2 | c.5188G>A p.E1730K | Missense Mutation (SNP) | VAF 115/273 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs948765391; called by muse, mutect2, varscan2
- HTR1E | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1240014715, COSV100541214; called by muse, mutect2
- HUWE1 | c.4093C>T p.R1365W | Missense Mutation (SNP) | VAF 153/416 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs781945789, COSV99029172; called by muse, mutect2, varscan2
- HUWE1 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV53342671; called by muse, mutect2, varscan2
- IDS | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1557340605; called by muse, mutect2, varscan2
- IFI27L1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 118/381 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.146); catalogued as rs545021441, COSV67628622; called by muse, mutect2, varscan2
- IFNA13 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs1164592178, COSV71924451; called by muse, mutect2, varscan2
- IFNB1 | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 114/326 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV66525246; called by muse, mutect2, varscan2
- IFNB1 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs916446914; called by muse, mutect2, varscan2
- IFRD1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 153/392 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV99133878; called by muse, mutect2, varscan2
- IGHG3 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 287/825 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs1389574284; called by muse, mutect2, varscan2
- IGHV3-53 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 160/398 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.393); catalogued as rs782705957; called by muse, mutect2, varscan2
- IGKV4-1 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 108/273 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs371960591; called by muse, mutect2, varscan2
- IGSF10 | c.4744G>T p.E1582* | Nonsense Mutation (SNP) | VAF 100/334 reads (30%) | catalogued as COSV56790165, COSV99198746; called by muse, mutect2, varscan2
- IL16 | c.303C>A p.F101L | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57263269; called by muse, mutect2, varscan2
- IL1RAPL1 | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV56281070; called by muse, varscan2
- IL22RA1 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1307905140, COSV99583200; called by muse, mutect2, varscan2
- IL7R | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 115/266 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs769324453, COSV100286370; called by muse, mutect2, varscan2
- IL9R | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 146/413 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99729171; called by muse, mutect2, varscan2
- ILDR1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747963872, COSV56550154, COSV99878285; called by muse, mutect2, varscan2
- ILDR2 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142876093; called by muse, mutect2, varscan2
- IMMP1L | c.454G>T p.G152* | Nonsense Mutation (SNP) | VAF 62/195 reads (32%) | catalogued as rs772546006; called by muse, mutect2, varscan2
- IMPDH2 | c.1247C>A p.S416Y | Missense Mutation (SNP) | VAF 116/308 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58245552; called by muse, mutect2, varscan2
- INAVA | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 95/220 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775847066; called by muse, mutect2, varscan2
- INPPL1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 96/251 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as rs762663532, COSV53354604; called by muse, mutect2, varscan2
- INSR | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 34/476 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV57170944; called by muse, mutect2
- INSRR | c.2809C>A p.L937I | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.978); catalogued as COSV100947199; called by muse, mutect2
- INTS1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV101248287; called by muse, mutect2, varscan2
- INTS4 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.313); catalogued as rs867570154; called by muse, mutect2, varscan2
- INTS5 | c.2902C>T p.R968C | Missense Mutation (SNP) | VAF 128/307 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV100399394; called by muse, mutect2, varscan2
- INVS | c.3079C>T p.R1027C | Missense Mutation (SNP) | VAF 101/215 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.232); catalogued as rs771248759, COSV52451299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IP6K2 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 99/249 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV60793828; called by muse, mutect2, varscan2
4,628 further variants in this file (3,097 protein-altering or splice-affecting, 873 silent, 658 other) are not listed here.
